CCDI case PBCSEZ — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS; Primary site: Brain.
https://portal.gdc.cancer.gov/cases/9bbbeece-4032-4aaf-b58b-a079da6c41bf

Demographics
Sex at birth: male; Race: white.

Diagnoses (1)
1. Choroid plexus papilloma, NOS: ICD-O-3 morphology code: 9390/0; Tissue or organ of origin: Ventricle, NOS; Age at diagnosis: 0.8 years (293 days).

Biospecimens (3 samples)
- Sample 0DYB0G: Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DYB0N: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Sample 0DYB0Y: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
